Surgical pathology report (de-identified scan), TCGA case TCGA-AO-A126, project TCGA-BRCA (Breast Invasive Carcinoma), tissue source site MSKCC, specimen TCGA-AO-A126-01A (Primary Tumor).

[page 1 of 5]
Clinical Diagnosis and History:

year old with newly diagnosed right breast cancer, core biopsy proven. Now scheduled for right total mastectomy with SLNB and possible ALND with immediate reconstruction TE.

Specimens Submitted:

- 1: SP: Sentinel node #1, level 1, right axilla
- 2: SP: Sentinel node #2, level 1, right axilla
- 3: SP: Sentinel node #3, level 1, right axilla
- 4: SP: Sentinel node #4, level 1, right axilla
- 5: SP: Rt. breast
- 6: SP: Non sentinel node, rt. axilla

DIAGNOSIS:

- 1) LYMPH NODE, SENTINEL #1, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 2) LYMPH NODE, SENTINEL #2, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 3) LYMPH NODE, SENTINEL #3, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 4) LYMPH NODE, SENTINEL #4, LEVEL I, RIGHT AXILLA; EXCISION:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).
- DEEPER LEVEL RECUTS AND SPECIAL STAINS HAVE BEEN ORDERED.
THE RESULTS WILL BE REPORTED IN AN ADDENDUM.
- 5) BREAST, RIGHT; SIMPLE MASTECTOMY:
- INVASIVE DUCTAL CARCINOMA, GROWING IN SOLID, TUBULAR, AND CRIBRIFORM PATTERNS.
- HISTOLOGIC GRADE II/III (MODERATE TUBULE FORMATION),
NUCLEAR GRADE II/III (MODERATE VARIATION IN SIZE AND SHAPE),
MEASURING 2.5 CM IN LARGEST DIMENSION GROSSLY.
- THE INVASIVE CARCINOMA IS LOCATED IN THE UPPER-INNER QUADRANT.
- NO INVOLVEMENT OF THE NIPPLE BY EITHER IN-SITU OR INVASIVE CARCINOMA IS IDENTIFIED.

PATH
REPORT
11

** Continued on next page **

1CD-0-3

Carcinoma, infiltrating ductal, NOS 8500/3
Site: breast, NOS C50.9 10/22/11

Re-reviewer Initials: WJ Date Reviewed: 10/22/11		

[page 2 of 5]
----- Page 2 of 5

- NO CALCIFICATIONS ARE IDENTIFIED IN EITHER THE INVASIVE COMPONENT OR IN BENIGN BREAST PARENCHYMA.
- NO VASCULAR INVASION IS NOTED.
- INVASIVE CARCINOMA IS 0.5 CM FROM THE NEAREST (DEEP) MARGIN.
- NO SKIN INVOLVEMENT BY CARCINOMA IS IDENTIFIED.
- THE NON-NEOPLASTIC BREAST TISSUE SHOWS BIOPSY SITE CHANGES, FIBROCYSTIC CHANGES, AND FIBROADENOMATOID CHANGE.
- RESULTS OF SPECIAL STAINS (ER, PR, HER2-NEU) WILL BE REPORTED AS AN ADDENDUM.

2

- 6) LYMPH NODE, NON-SENTINEL, RIGHT AXILLA:
- ONE LYMPH NODE, NEGATIVE FOR TUMOR (0/1).

:

** Report Electronically Signed Out **

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

Special Studies:

Stain/Procedure Name	Result	Comment
KERATIN (CAM5.2)		
AE1:AE3		
NEGATIVE CONTROL		
IMMUNO RECUT		
AE1:AE3		
KERATIN (CAM5.2)		
KERATIN (CAM5.2)		
AE1:AE3		
NEGATIVE CONTROL		
IMMUNO RECUT		
KERATIN (CAM5.2)		
AE1:AE3		
NEGATIVE CONTROL		
IMMUNO RECUT		
ESTROGEN RECEPTOR		
PROGESTERONE RECEPTOR		
HER2-C		
NEGATIVE CONTROL		
IMMUNO RECUT		
NEGATIVE CONTROL FOR HER2		

Gross Description:

** Continued on next page **

PATH
REPORT
11

[page 3 of 5]
1) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel Node #1, Level 1, Right Axilla". It consists of one firm, brown-tan node, measuring 0.7 x 0.4 x 0.3 cm. Bisected and entirely frozen.

Summary of Sections:

FSC - frozen section control

2) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel Node #2, Level 1, Right Axilla". It consists of one firm, brown-tan node, measuring 0.2 x 0.1 x 0.1 cm. Bisected and entirely submitted.

Summary of Sections:

FSC - frozen section control

3) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel Node #3, Level 1, Right Axilla". It consists of one firm, brown-tan lymph node, measuring 1.2 x 0.4 x 0.2 cm. Bisected and entirely submitted.

Summary of Sections:

FSC - frozen section control

4) The specimen is received fresh for frozen section diagnosis, labeled, "Sentinel Node #4, Level 1, Right Axilla". It consists of one firm, brown-tan lymph node, measuring 0.8 x 0.3 x 0.2 cm. Entirely submitted.

Summary of Sections:

FSC - frozen section control

5) The specimen is received fresh, labeled, "Right breast, stitch marks axillary tail". It is a product of a right modified mastectomy consisting of an ellipse of tan skin with breast tissue. The ellipse of skin measures 9.0 x 3.0 cm. The breast tissue measures 17.0 x 15. x 7.0 cm. The nipple is inverted. No visible scars are identified. No visible scars identified from the skin surface. A scant amount of skeletal muscle is identified at the deep margin which is inked. The breast tissue was sectioned to reveal and ill-defined, indurated, gray white tumor measuring 2.5 x 1.5 x 2.0 cm and it is situated in the upper inner quadrant 1.0 cm from the deep surgical margin, 1.5 cm

PATH
REPORT
11

** Continued on next page **

[page 4 of 5]
----- Page 4 of 5

away from the mass and 2.5 cm from the deep surgical margin. In the upper outer quadrant is a smaller tumor nodule which measures 1.0 cm in greatest dimension (satellite nodules vs tumor extension). Spreading from the mass toward the outer aspect, is a diffuse area of fibrous tissue which is thickened and multinodular. The fibrous tissue constitutes approximately 45% of the breast tissue. The rest of the breast tissue is fatty and unremarkable. No lymph nodes were identified at the axillary tail site. The tumor was taken for TPS. Representative sections of the specimen are submitted.

Summary of Sections:

N - nipple
T - tumor
TN - separate tumor nodule
LIQ - lower inner quadrant
UOQ - upper outer quadrant
LOQ - lower outer quadrant
AXT - axillary tail site

6) The specimen is received in formalin, labeled, "Non-Sentinel Node Right". It consists of an irregularly-shaped portion of soft tissue, which measures 1.0 x 0.6 x 0.5 cm. The specimen is bisected and submitted entirely.

Summary of Sections:

L - lymph node

Summary of Sections:

Part	Sect.	Site	Blocks	Pieces	All
1	FSC		1	2	Y
2	FSC		1	2	Y
3	FSC		1	2	Y
4	FSC		1	2	Y
5	AXT		1	1	N
	LIQ		2	2	
	LOQ		2	2	
	N		2	2	
	T		3	3	
	TN		1	1	
	UOQ		2	2	
6	L		1	3	Y

Intraoperative Consultation:

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

- 1) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 2) FROZEN SECTION DIAGNOSIS: BENIGN. /
PERMANENT DIAGNOSIS: SAME.

PATH
REPORT
11

** Continued on next page **

[page 5 of 5]
- 3) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.
- 4) FROZEN SECTION DIAGNOSIS: BENIGN.
PERMANENT DIAGNOSIS: SAME.

ADDENDUM:

** SIGNED OUT **

ADDENDUM REPORT

SITE: SENTINEL LYMPH NODES RIGHT AXILLA
PART # 1,2,3, AND 4.

ADDITIONAL HE STAINED SECTIONS AND IMMUNOHISTOCHEMICAL
STAINS FOR CYTOKERATINS (AE1:AE3 AND CAM 5.2) SHOW NO
EVIDENCE OF METASTATIC TUMOR.

** Report Electronically Signed Out **

ADDENDUM:

** SIGNED OUT **

ADDENDUM REPORT

SITE: BREAST, RIGHT, SIMPLE MASTECTOMY
PART #5.

ER-ICA: POSITIVE

PR-ICA: POSITIVE

HER2/NEU (HERCEPT): NEGATIVE (STAINING INTENSITY OF 1+).

** Report Electronically Signed Out **

PATH
REPORT
11

** End of Report **

Source: NCI Genomic Data Commons file df632e65-e92c-4e86-b223-276cf759b702 (TCGA-AO-A126.A4BFA94D-166F-43D4-90B5-3C547F4026A0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).